Gene-level copy-number profile of tumor specimen ALCH-B2FH-TTP1-A from ALCHEMIST case ALCH-B2FH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.5 years (24,656 days).
Specimen ALCH-B2FH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5aa156e5-8d5b-4e12-bef2-754ed3a6c435.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/de63f34c-fc3f-402e-bd4e-c6f5bf4a2d5c

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 538; copy number 1: 37,298; copy number 2: 19,517; copy number 3: 818; copy number 4: 70; copy number 5: 281; copy number 6: 34; copy number 7: 5; copy number 8: 41; copy number 9: 26; copy number 10: 17; copy number 11: 27; copy number 12: 19; copy number 13: 3; copy number 14: 13; copy number 15: 33; copy number 16: 3; copy number 17: 19; copy number 20: 37; copy number 21: 5; copy number 22: 11; copy number 24: 21; copy number 25: 6; copy number 28: 9; copy number 29: 13; copy number 30: 3; copy number 34: 4; copy number 48: 3; copy number 71: 24; copy number 78: 5.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:69,922,751–69,987,697, 5 genes: RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20.
- chr13:112,106,095–112,106,882, 1 gene: LINC00404.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–1): TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,550 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,519,112–143,450,245, 7 genes, copy number 3–6: EMBP1, LINC01691, AC242852.1, AC242852.2, AC239859.5, RNA5SP533, AC239859.3.
- chr1:186,671,791–187,686,628, 4 genes, copy number 4 (within-gene range 2–4): PTGS2, PACERR, PLA2G4A, LINC01036.
- chr4:41,359,607–42,090,461, 18 genes, copy number 5: LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1.
- chr5:58,198–45,895,970, 679 genes, copy number 3–4 (broad region; genes not listed).
- chr8:65,644,734–67,056,604, 31 genes, copy number 11–29 (within-gene range 1–29): MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1.
- chr8:72,196,334–75,566,834, 68 genes, copy number 11–30 (broad region; genes not listed).
- chr8:78,268,637–78,558,503, 1 gene, copy number 4 (within-gene range 1–5): PKIA-AS1.
- chr8:78,516,340–78,805,523, 6 genes, copy number 5 (within-gene range 4–5): PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7.
- chr8:80,405,516–81,533,275, 33 genes, copy number 3: RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12.
- chr8:81,841,952–81,924,348, 1 gene, copy number 4 (within-gene range 1–4): LINC02235.
- chr8:95,066,808–95,156,685, 5 genes, copy number 4 (within-gene range 1–4): MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:119,350,291–123,737,402, 73 genes, copy number 3–20 (broad region; genes not listed).
- chr8:123,984,138–130,443,674, 100 genes, copy number 4–34 (within-gene range 1–34) (broad region; genes not listed).
- chr8:130,780,301–131,144,948, 4 genes, copy number 4: ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr8:132,507,962–134,390,487, 33 genes, copy number 11–21: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1.
- chr11:66,409,158–71,252,577, 165 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:70,626,441–73,181,724, 94 genes, copy number 3–5 (broad region; genes not listed).
- chr11:85,628,573–85,686,195, 4 genes, copy number 3: TMEM126B, TMEM126A, CREBZF, CCDC89.
- chr14:18,333,726–19,700,650, 68 genes, copy number 3 (broad region; genes not listed).
- chr14:31,489,956–31,861,224, 1 gene, copy number 20 (within-gene range 2–20): NUBPL.
- chr14:31,662,039–38,987,383, 124 genes, copy number 6–78 (broad region; genes not listed).
- chr16:52,238,081–52,547,802, 4 genes, copy number 3: AC007333.1, CASC22, TOX3, AC007490.1.
- chr17:48,133,442–48,430,275, 5 genes, copy number 3 (within-gene range 2–3): SKAP1, MIR1203, SKAP1-AS1, RNU6-1152P, THRA1/BTR.
- chr18:69,212,277–70,650,744, 20 genes, copy number 3: AC090337.1, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1.
- chr21:10,640,028–10,649,835, 2 genes, copy number 3: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 35,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
